Gene-level copy-number profile of tumor specimen ALCH-B2FE-TTP1-A from ALCHEMIST case ALCH-B2FE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,708 days).
Specimen ALCH-B2FE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d4a032b-0d04-438e-9b8f-1ca233d6351f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/25a58eb8-6d30-4284-b428-7c7ed3a46012

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,590; copy number 2: 51,494; copy number 3: 3,175; copy number 4: 122; copy number 5: 5; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:110,502,575–110,508,179, 1 gene (within-gene range 0–2): COL4A2-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,103,719–5,120,245, 1 gene, copy number 5: OR10AH1P.
- chr15:101,875,964–101,876,901, 1 gene, copy number 5: OR4F28P.
- chr15:101,954,885–101,961,408, 3 genes, copy number 5: FAM138E, AC140725.1, MIR1302-10.
- chr20:64,290,187–64,313,132, 2 genes, copy number 19: CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 3,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
